Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9JD, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9JD-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

ICD-O-3
Carcinoma, papillary renal
cell 8260/3
Site: R Kidney NOS C64.9
QW 4/28/14

Final Diagnosis

- A. "RIGHT PERITUMORAL FAT," PARTIAL NEPHRECTOMY:
Fibroadipose tissue, negative for carcinoma.
- B. "RIGHT RENAL MASS INFERIOR MARGIN," PARTIAL NEPHRECTOMY:
Fibroadipose tissue, negative for carcinoma.
- C. "RIGHT RENAL MASS SUPERIOR MARGIN," PARTIAL NEPHRECTOMY:
Fibroadipose tissue, negative for carcinoma.
- D. "RIGHT RENAL MASS POSTERIOR MARGIN," PARTIAL NEPHRECTOMY:
Fibroadipose tissue, negative for carcinoma.
- E. "RIGHT RENAL MASS," PARTIAL NEPHRECTOMY:
Renal cell carcinoma, papillary type 2, Fuhrman nuclear grade 3 of 4.
Papillary adenoma, 0.1 cm (size as measured on slide).
See Key Pathological Findings.

I, _____ the attending pathologist, personally reviewed the entire case and rendered the final diagnosis. Electronically Signed Out by _____

Key Pathological Findings

Tumor type:	Renal cell carcinoma, papillary type 2.
Nuclear grade:	Fuhrman nuclear grade 3 of 4.
Pattern of growth:	Papillary.
Tumor size:	4.0 cm (size of tumor based on current specimen).
Invasion through Renal capsule:	Not identified.
Invasion of Gerota's Fascia:	Not applicable.
Renal vein invasion:	Not applicable.
Surgical margins:	Free.
Non-neoplastic kidney:	Mild chronic inflammation and focal glomerulosclerosis.
Adrenal gland:	Not applicable.
Lymph nodes:	Not applicable.
Pathologic stage:	pT1aNXMX (size of tumor based on current specimen).

Specimen(s) Received

- A RIGHT PERITUMORAL FAT
B RIGHT RENAL MASS INFERIOR MARGIN FS
C RIGHT RENAL MASS SUPERIOR MARGIN FS
D RIGHT RENAL MASS POSTERIOR MARGIN FS
E RIGHT RENAL MASS FS

Clinical History

Renal cell carcinoma, status post right partial nephrectomy.

[page 2 of 3]
Preoperative Diagnosis

Renal cell carcinoma, status post right partial nephrectomy.

Intraoperative Consultation

FSB1. RIGHT RENAL MASS INFERIOR MARGIN:

Perpendicular cross section, adipose tissue - not cut, negative.

FSC1. RIGHT RENAL MASS SUPERIOR MARGIN:

Perpendicular, adipose tissue, not cut well, negative.

FSD1. RIGHT RENAL MASS POSTERIOR MARGIN:

Perpendicular, negative (adipose tissue, not cut well).

Comment: These frozen section diagnoses/results were communicated to and acknowledged by Dr.

I, _____, have performed the intraoperative consultations and issued the above diagnoses.

Gross Description

A. The specimen is received fresh labeled "right peritumoral fat." The specimen consists of multiple, irregular, unoriented fragments of lobulated adipose tissue, which range from 1 to 3.5 cm in greatest dimension. The specimen is serially sectioned to reveal a grossly unremarkable cut surface. No tissue is submitted to the Tissue Procurement Laboratory. Representative sections of the specimen are submitted in 5 cassettes, A1-A5.

B. The specimen is received fresh labeled "right renal mass, inferior margin." The specimen consists of an irregular fragment of fibroadipose tissue measuring 1.2 x 0.6 x 0.6 cm. The specimen is oriented according to the surgeon's designation and inferior margin is inked blue. The specimen is bisected and submitted entirely for frozen section as FSB1.

C. The specimen is received fresh labeled "right renal mass, superior margin." The specimen consists of an irregular fragment of fibroadipose tissue measuring 1.5 x 0.4 x 0.3 cm. The specimen is oriented according to the surgeon's designation and the superior margin is inked black. The specimen is bisected and submitted entirely for frozen section as FSC1.

D. The specimen is received fresh labeled "right renal mass, posterior margin." The specimen consists of an irregular fragment of fibroadipose tissue measuring 1.2 cm in greatest dimension. The specimen is oriented according to the surgeon's designation and the posterior margin is inked black. No tissue was submitted to the Tissue Procurement Laboratory. The specimen is submitted entirely for frozen section as FSD1.

E. The specimen is received fresh labeled "right renal mass." The specimen consists of a partial nephrectomy with a moderate amount of lobulated adipose tissue of the renal hilum attached. The specimen measures 7 x 4 x 4.5 cm. The specimen is oriented by a surgeon and is inked as follows: parenchymal resection margin is inked black, anterior adipose tissue resection margin is inked green,

[page 3 of 3]
posterior orange, superior black, inferior blue. On sectioning, the specimen reveals a roughly ovoid, ill-defined rubbery tumor mass, which measures 4 x 4 x 3.8 cm. Cut surface of the tumor is tan-red-brown, focally hemorrhagic. The tumor is bulging capsule and extends to within 0.2 cm of the closest parenchyma resection margin. Representative sections of the specimen are submitted to the Tissue Procurement Laboratory. The superior, inferior, and posterior resection margins are received for frozen section analysis in separate contains. Representative sections of the specimen are submitted in 10 cassettes as follows:

- E1-E2: Tumor in relation to the closest anterior adipose tissue resection margin.
E3-E10: Tumor in relation to the closest parenchymal resection margin, perpendicular sections.

Cassette E10 mirror image of the section submitted to the Tissue Procurement Laboratory.

Source: NCI Genomic Data Commons file 27daf303-fb11-4fcd-8fe4-840a494560b5 (TCGA-2Z-A9JD.9D430275-A98A-4C89-BE8A-95D5DDB1BC8B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).